BEATAML1.0 case 2146 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myelodysplastic Syndromes; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/e2b45d76-2ff7-446a-b37a-c6a718005538

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Myelodysplastic syndrome, unclassifiable: ICD-O-3 morphology code: 9989/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,531 days); Progression or recurrence: no; ELN risk classification: Adverse.

Biospecimens (2 samples)
- Sample BA2801D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample BA2801R: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
